Somatic mutation profile of tumor specimen 0E1HF6 from CCDI case PBCWHI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0E1HF6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ffe12770-54d4-42f0-bb45-681db540d660.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1HG2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a1ce5d10-f87e-4848-8a07-4539a1e805bd

The open-access MAF lists 28 somatic variants for this specimen: 22 protein-altering or splice-affecting, 1 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Intron 3, Frame Shift Del 3, Silent 1, 5'Flank 1, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 486/852 reads (57%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 284/1124 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- BPIFA3 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 238/853 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs189260453; called by muse, varscan2
- GLB1 | c.1695G>T p.L565F | Missense Mutation (SNP) | VAF 191/556 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.628); catalogued as rs748372075; called by muse, varscan2
- LAMA3 | c.1535G>A p.R512H | Missense Mutation (SNP) | VAF 294/772 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.073); catalogued as rs759176445, COSV58077949; called by muse, varscan2
- LSM14A | c.1268G>A p.R423H | Missense Mutation (SNP) | VAF 190/538 reads (35%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.987); catalogued as rs370562803; called by muse, varscan2
- MAPK8IP1 | c.1076C>T p.P359L | Missense Mutation (SNP) | VAF 180/449 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs1364573192, COSV53799470; called by muse, varscan2
- POSTN | c.2257C>T p.R753* | Nonsense Mutation (SNP) | VAF 220/898 reads (24%) | catalogued as rs1342114846, COSV65712370, COSV65713059; called by muse, varscan2
- PTPN3 | c.577G>C p.E193Q | Missense Mutation (SNP) | VAF 165/474 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as COSV52706969; called by muse, varscan2
- TENM3 | c.4909C>T p.R1637C | Missense Mutation (SNP) | VAF 174/520 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs986706267, COSV69303922; called by muse, varscan2
- USP20 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 121/342 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777767168, COSV100205134; called by muse, varscan2
- ZNF609 | c.1318C>T p.R440W | Missense Mutation (SNP) | VAF 182/535 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1304725927; called by muse, varscan2
- AC242842.3 | c.11456T>G p.L3819W | Missense Mutation (SNP) | VAF 510/974 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.178); called by muse, varscan2
- BAHCC1 | c.2255_2273del p.E752Gfs*24 | Frame Shift Del (DEL) | VAF 136/533 reads (26%) | called by pindel, varscan2
- CACHD1 | c.2068C>G p.R690G | Missense Mutation (SNP) | VAF 330/826 reads (40%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.953); called by muse, varscan2
- CCDC18 | c.1510C>G p.Q504E (on ENST00000343253 / NM_001306076.1; = p.Q505E on NM_206886.4) | Missense Mutation (SNP) | VAF 180/1009 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.059); called by muse, varscan2
- CIBAR1 | c.72G>T p.E24D | Missense Mutation (SNP) | VAF 207/766 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); called by muse, varscan2
- CREBBP | c.1108_1112del p.R370Afs*55 | Frame Shift Del (DEL) | VAF 270/765 reads (35%) | called by pindel, varscan2
- H4C5 | c.50A>T p.K17M | Missense Mutation (SNP) | VAF 362/934 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.084); called by muse, varscan2
- SYK | c.1896C>G p.D632E | Missense Mutation (SNP) | VAF 192/532 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, varscan2
- TMEM178A | c.782C>A p.A261D | Missense Mutation (SNP) | VAF 264/1030 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- ZNF385A | c.863del p.G288Afs*10 (on ENST00000338010 / NM_001130967.3; = p.G268Afs*10 on NM_015481.3) | Frame Shift Del (DEL) | VAF 161/791 reads (20%) | called by pindel, varscan2
- FSIP2 | c.19620C>T p.H6540= | Silent (SNP) | VAF 198/757 reads (26%) | called by muse, varscan2
- ANTXR2 | chr4:80072607 G>T | 5'Flank (SNP) | VAF 100/232 reads (43%) | called by muse, varscan2
- CCDC157 | c.1672+85G>T | Intron (SNP) | VAF 108/282 reads (38%) | called by muse, varscan2
- GFRA2 | c.-35-24T>C | Intron (SNP) | VAF 40/102 reads (39%) | called by muse, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 20/191 reads (10%) | called by muse, varscan2
- RTCB | c.240+72G>A | Intron (SNP) | VAF 70/177 reads (40%) | called by muse, varscan2
